Somatic mutation profile of tumor specimen 0DU7AC from CCDI case PBCKSJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Upper respiratory tract, NOS; Age at diagnosis: 4.1 years (1,504 days).
Specimen 0DU7AC: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3817a425-56fe-4a43-a621-fa7b8f9d6ee6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU7A7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0411bea-aedf-48e0-8e85-b975e868cac5

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OGT | c.2783A>G p.N928S | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MYO9A | c.3294G>A p.R1098= | Silent (SNP) | VAF 19/563 reads (3%) | called by muse, mutect2
- MYOM2 | c.3044-58T>C | Intron (SNP) | VAF 10/132 reads (8%) | catalogued as rs1224509451; called by muse, mutect2
